Surgical pathology report (de-identified scan), TCGA case TCGA-76-4928, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-4928-01B (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. SPECIMEN DESIGNATED "Left temporal primary tumor": glioblastoma multiforme (who grade iv)
2. SPECIMEN DESIGNATED "Left temporal primary tumor": glioblastoma multiforme (who grade iv), see microscopic description.

[REDACTED]
Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.

[REDACTED]

Microscopic Description:

The tumor is composed of pleomorphic glial cells. Mitotic figures are identified in tumor cells. Tumor necrosis is present. The immunohistochemical stain for glial fibrillary acidic protein (GFAP) is positive in tumor cells. The proliferation index as determined by nuclear staining of tumor cells with the Ki67 (MIB-1) immunohistochemical stain is approximately 25%.

Frozen Section Diagnosis:

1. Left temporal primary tumor: Glioblastoma multiforme

Source of Specimen:

[page 2 of 3]
- 1: Left temporal primary tumor
2: Left temporal primary tumor

Gross Description:

1. Left temporal primary tumor: Received fresh are two fragments of soft pink-tan tissue that measure 1 x 0.9 x 0.4 cm. Touch preps are prepared. The entire specimen is submitted for frozen section in one cassette.

2. Left temporal primary tumor: Received in formalin are multiple fragments of soft brown pink tissue that measure 1.5 x 1.2 x 0.6 cm. The entire specimen is submitted for permanent section in two cassettes.

Histology Laboratory
H&E

Panel 2: Left temporal primary tumor
UNSTAINED

[page 3 of 3]
[REDACTED]

Patient: [REDACTED]

IMMUNOPATHOLOGY REPORT

EVALUATION:

gfap: positive staining in tumor cells.

ki67: positive staining in approximately 25% of tumor cell nuclei.

hmb45: negative in tumor cells.

Comment:

The immunohistochemical stains support the diagnosis of glioblastoma multiforme (WHO grade IV). See corresponding surgical pathology report [REDACTED]

[REDACTED]

Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.
[REDACTED]

Source: NCI Genomic Data Commons file 2fc4d4cb-c133-4094-a937-5bcf79fa0005 (TCGA-76-4928.DAD54EBF-DA45-4E1E-91E3-DD56B2B96597.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).